Somatic mutation profile of tumor specimen MP2PRT-PARKAZ-TMP1-B (aliquot MP2PRT-PARKAZ-TMP1-B-1-0-D-A834-36) from MP2PRT case MP2PRT-PARKAZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,275 days).
Specimen MP2PRT-PARKAZ-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3cbb9148-22bf-4f54-9bf5-280ef27f4196.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARKAZ-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARKAZ-NM1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a05aa84-5be1-40e0-999f-de2f652ee118

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 7, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 60/542 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CCDC183 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 30/462 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs1459682384; called by muse, mutect2
- CD300LG | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 55/375 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755265245; called by muse, mutect2, varscan2
- ITGB3 | c.1763C>T p.T588M | Missense Mutation (SNP) | VAF 52/581 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs762965827, COSV71385247; called by muse, mutect2
- SRMS | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 151/937 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs751206072, COSV99420932; called by muse, mutect2, varscan2
- TRABD2A | c.1174G>A p.V392I (on ENST00000409520 / NM_001277053.2; = p.V343I on NM_001080824.3) | Missense Mutation (SNP) | VAF 133/882 reads (15%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs560540640, COSV52863071; called by muse, mutect2, varscan2
- KLHL38 | c.1696C>A p.H566N | Missense Mutation (SNP) | VAF 76/702 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GRM5 | c.3168C>A p.S1056= (on ENST00000305447 / NM_001143831.2; = p.S1024= on NM_000842.4) | Silent (SNP) | VAF 188/1257 reads (15%) | called by muse, mutect2, varscan2
- ODF3L2 | c.693G>A p.P231= | Silent (SNP) | VAF 170/1119 reads (15%) | catalogued as rs1288140639, COSV52746541; called by muse, mutect2, varscan2
- SLC25A29 | c.384G>A p.A128= (on ENST00000359232 / NM_001039355.3; = p.A62= on NM_152333.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 85/1527 reads (6%) | catalogued as rs958197864; called by muse, mutect2
- SMTNL2 | c.1218G>A p.T406= (on ENST00000389313 / NM_001114974.2; = p.T262= on NM_198501.3) | Silent (SNP) | VAF 82/604 reads (14%) | catalogued as rs1293688644, COSV58807041; called by muse, mutect2, varscan2
- TRRAP | c.2700C>T p.G900= | Silent (SNP) | VAF 113/756 reads (15%) | called by muse, mutect2, varscan2
